Somatic mutation profile of tumor specimen MP2PRT-PAUBSM-TMP1-A (aliquot MP2PRT-PAUBSM-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUBSM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,685 days).
Specimen MP2PRT-PAUBSM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12202973-a542-48ee-8cfc-a293696914c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUBSM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUBSM-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11ca963f-11f7-4d6b-91f7-58e5d941b22f

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SHROOM2 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 79/705 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs756155141, COSV66607465; called by muse, mutect2, varscan2
- WDFY3 | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371738138; called by muse, mutect2, varscan2
- ABCC6 | c.512_513insGGC p.Y171delins* | Nonsense Mutation (INS) | VAF 62/246 reads (25%) | called by mutect2, pindel*, varscan2
- KLHL35 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 44/858 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- PAAF1 | c.1069C>A p.L357I | Missense Mutation (SNP) | VAF 92/334 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- DOK2 | c.783C>T p.P261= | Silent (SNP) | VAF 52/632 reads (8%) | catalogued as rs749307499; called by muse, mutect2
- EPS15 | c.1770C>T p.D590= | Silent (SNP) | VAF 88/258 reads (34%) | called by muse, mutect2, varscan2
